Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3980, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3980-01A (Primary Tumor).

The material in Block A is an invasive carcinoma, and adenocarcinoma of the colon, characterized here as a serrated adenocarcinoma of grade G2 with infiltration of the muscularis pT2 with vascular infiltration L1, V1.

In the region of the mucosa, it also shows free mucosal margins with a regular mucosa, submucosa and muscularis and regular fatty connective tissue in the direction of the central ligature.

The material in Block D is additionally a polyp characterized as a serrated adenoma without dysplasia (not a high-grade neoplasia), free lymph nodes with a marked resorptive lymphadenitis, in relation to the macroscopically named adjacent node likewise a regular lymph node and in relation to Block H the formation of a diverticulum, here typically in the sense of a pseudodiverticulum with an eversion between the gaps in the muscle wall.

In relation to the the central resection margin: mature fatty connective tissue with dilated vessels and, in relation to the lymph nodes, a chronic resorptive lymphadenitis.

Tumor classification:

ICDO-DA-M

G 2

pT2

L1, V1

pN0 (0 of 18 + 1) with complete local excision

Source: NCI Genomic Data Commons file a833f487-c546-4138-8dcd-2a88481e3b27 (TCGA-AA-3980.336FE62C-A0FD-4E99-93DD-15D755BD709B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).